Somatic mutation profile of tumor specimen TCGA-WB-A81H-01A (aliquot TCGA-WB-A81H-01A-11D-A35I-08) from TCGA case TCGA-WB-A81H, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 45.0 years (16,425 days).
Specimen TCGA-WB-A81H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f342fc7-4bcd-4b4c-b8ea-f2d3c0a1e88f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A81H-10A (Blood Derived Normal), aliquot TCGA-WB-A81H-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f34abb2a-d8d0-4b3f-b22f-c82fc9f7625d

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Frame Shift Del 3, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTN | c.44248C>T p.R14750* (on ENST00000591111; = p.R7326* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as rs570046043; ClinVar: likely pathogenic; called by muse, mutect2
- CYP4F2 | c.748A>G p.T250A | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs767214008; called by muse, mutect2, varscan2
- GPX4 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as rs747887804, COSV62322890; called by muse, mutect2, varscan2
- MUC5B | c.11010C>A p.H3670Q | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as rs1303330338; called by muse, mutect2
- NFE2L3 | c.1596_1599del p.D532Efs*3 | Frame Shift Del (DEL) | VAF 29/107 reads (27%) | catalogued as rs867593033; called by mutect2, pindel, varscan2
- OPRPN | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 25/253 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.148); catalogued as COSV68193445; called by muse, mutect2
- NAV3 | c.2099T>C p.M700T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- NF1 | c.3011_3026del p.N1004Ifs*3 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel
- RPS6KC1 | c.2808A>T p.L936F | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RTN4 | c.2325_2328del p.F776Sfs*3 | Frame Shift Del (DEL) | VAF 21/109 reads (19%) | called by mutect2, pindel, varscan2
- LANCL1 | c.858C>T p.L286= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs747034923; called by muse, mutect2
